Somatic mutation profile of tumor specimen ALCH-B4RW-TTP1-A (aliquot ALCH-B4RW-TTP1-A-3-0-D-A81V-36) from ALCHEMIST case ALCH-B4RW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.2 years (30,039 days).
Specimen ALCH-B4RW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4400f7bb-2d4c-406a-9441-f577fb3cbf92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4RW-NB1-A (Blood Derived Normal), aliquot ALCH-B4RW-NB1-A-2-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dff2cbed-3e9e-4478-a543-eedfe66bed17

The open-access MAF lists 100 somatic variants for this specimen: 70 protein-altering or splice-affecting, 20 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, Nonsense Mutation 7, Intron 5, Splice Site 2, Frame Shift Del 2, 5'Flank 2, Frame Shift Ins 1, RNA 1, 3'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 187/501 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761500934, COSV57009375; called by muse, mutect2
- ARHGEF10L | c.2831G>A p.G944E | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51441527; called by muse, varscan2
- ARID1A | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 50/238 reads (21%) | catalogued as COSV61371253; called by muse, mutect2, varscan2
- CNTLN | c.3467G>A p.R1156Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs766597821, COSV52066609; called by muse, mutect2, varscan2
- ENTHD1 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs144803190; called by muse, mutect2, varscan2
- FBXL5 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 55/303 reads (18%) | catalogued as COSV100377691; called by muse, mutect2, varscan2
- GPR6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.362); catalogued as rs1274651473, COSV51573848; called by muse, mutect2, varscan2
- HTR2A | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1222375103, COSV66326961; called by muse, mutect2
- IGKV1D-8 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758838114; called by muse, mutect2
- ITGA11 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759749390; called by muse, mutect2, varscan2
- KIAA0100 | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 61/388 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs139897386; called by muse, mutect2, varscan2
- L3MBTL4 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 44/413 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53125260; called by muse, mutect2, varscan2
- MLN | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs746105078, COSV99803045; called by muse, mutect2
- MYO5B | c.4020C>T p.A1340= | Splice Region (SNP) | VAF 36/404 reads (9%) | catalogued as rs543542098; called by muse, mutect2
- OR4K2 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs763057080, COSV100064325, COSV53848263; called by muse, mutect2
- OSBPL9 | c.1847A>G p.K616R | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV61403762; called by muse, mutect2, varscan2
- PPFIA3 | c.2743A>G p.T915A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1293378693; called by mutect2, varscan2
- PRR23B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.211); catalogued as rs754211034, COSV61493204; called by muse, varscan2
- RETREG1 | c.1312C>T p.Q438* (on ENST00000306320 / NM_001034850.2; = p.Q297* on NM_019000.4) | Nonsense Mutation (SNP) | VAF 40/228 reads (18%) | catalogued as COSV60447885; called by muse, mutect2, varscan2
- SLC22A6 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 63/391 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100842878; called by muse, mutect2, varscan2
- SLC25A19 | c.185T>A p.I62N | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57468403; called by muse, mutect2, varscan2
- SMYD1 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs985490962; called by muse, mutect2, varscan2
- TBATA | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs528706623; called by muse, mutect2, varscan2
- THSD1 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs767635196, COSV51629553; called by muse, mutect2, varscan2
- ACVRL1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAM15 | c.131T>G p.L44W | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ADCY5 | c.2901-1G>A p.X967_splice | Splice Site (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- ANK3 | c.12449C>T p.T4150I (on ENST00000280772 / NM_001320874.2; = p.T671I on NM_001149.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- C8orf34 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARMIL1 | c.826T>G p.S276A | Missense Mutation (SNP) | VAF 51/474 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC7 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2
- CDH17 | c.2228del p.L743* | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel, varscan2
- CHAMP1 | c.1801del p.L601* | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- CHL1 | c.3134T>A p.V1045D (on ENST00000397491 / NM_001253387.1; = p.V1061D on NM_006614.4) | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DNAH11 | c.9382C>T p.Q3128* | Nonsense Mutation (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- DYSF | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GJD4 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.36); called by muse, mutect2
- GSDMD | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.272); called by muse, varscan2
- HCN1 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 42/445 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- HPS4 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 35/299 reads (12%) | called by muse, mutect2, varscan2
- INPP5F | c.2238G>T p.K746N | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2
- INSYN2B | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.037); called by muse, mutect2
- KLHL1 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- LEMD1 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 57/346 reads (16%) | called by muse, mutect2, varscan2
- LEMD1 | c.294A>C p.K98N | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2
- MACF1 | c.7375dup p.T2459Nfs*3 | Frame Shift Ins (INS) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- MDM1 | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 17/392 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2
- MUC4 | c.9031G>T p.V3011F | Missense Mutation (SNP) | VAF 89/582 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, varscan2
- MYOM1 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- NDST1 | c.1567-2A>T p.X523_splice | Splice Site (SNP) | VAF 36/190 reads (19%) | called by muse, mutect2, varscan2
- NDUFA9 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- NTRK2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.587); called by muse, mutect2
- OR2A7 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 20/774 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- PCDHA9 | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- POLE | c.5738T>G p.F1913C | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PPIL1 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RETREG1 | c.1190C>T p.T397I (on ENST00000306320 / NM_001034850.2; = p.T256I on NM_019000.4) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SAMD9 | c.990C>A p.N330K | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETBP1 | c.1792G>T p.V598F | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA12 | c.517T>A p.F173I | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2
- STARD9 | c.2215G>C p.V739L | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- STK31 | c.181A>T p.I61F | Missense Mutation (SNP) | VAF 86/324 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.637); called by muse, varscan2
- TECPR2 | c.2485A>T p.K829* | Nonsense Mutation (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- TENM4 | c.7880G>C p.G2627A | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMEM132C | c.1152G>C p.Q384H | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- TNPO3 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UNC5A | c.2435T>C p.F812S | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ZNF726 | c.1738C>A p.L580I | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ZNF808 | c.632A>G p.N211S | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2
- ACKR3 | c.771C>T p.Y257= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as rs572775769, COSV56021014; called by muse, mutect2, varscan2
- AGBL1 | c.3084G>T p.L1028= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ARHGEF10L | c.2832G>A p.G944= | Silent (SNP) | VAF 22/193 reads (11%) | called by muse, varscan2
- ATR | c.840T>G p.L280= | Silent (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- COL20A1 | c.1317C>T p.R439= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, varscan2
- DNAH5 | c.11982C>T p.F3994= | Silent (SNP) | VAF 58/467 reads (12%) | catalogued as rs1420205236; called by mutect2, varscan2
- FASN | c.2046C>T p.F682= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as rs778418702, COSV60752763, COSV60762827; called by muse, mutect2, varscan2
- FBXL7 | c.570C>A p.T190= | Silent (SNP) | VAF 113/379 reads (30%) | called by muse, mutect2, varscan2
- GTF3C1 | c.900C>T p.A300= | Silent (SNP) | VAF 78/362 reads (22%) | catalogued as rs767445281; called by muse, mutect2, varscan2
- MBTPS2 | c.1374T>A p.V458= | Silent (SNP) | VAF 16/344 reads (5%) | called by muse, mutect2
- OR2T1 | c.417C>A p.V139= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV63541719; called by muse, mutect2, varscan2
- PDE3A | c.1485A>T p.S495= | Silent (SNP) | VAF 14/396 reads (4%) | catalogued as COSV62976987; called by muse, mutect2
- PRAMEF17 | c.1269T>G p.G423= | Silent (SNP) | VAF 59/523 reads (11%) | called by muse, mutect2, varscan2
- SCN4A | c.903C>T p.Y301= | Silent (SNP) | VAF 45/828 reads (5%) | catalogued as rs201411232, COSV71129963; ClinVar: benign / likely benign; called by muse, mutect2
- SHANK3 | c.2199C>T p.V733= | Silent (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- SLC26A3 | c.1531C>T p.L511= | Silent (SNP) | VAF 13/377 reads (3%) | called by muse, mutect2
- SLC9A3 | c.1245C>T p.R415= | Silent (SNP) | VAF 34/540 reads (6%) | catalogued as rs143761751, COSV99375879; called by muse, mutect2
- SMAD6 | c.1368C>T p.D456= | Silent (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2
- TIMELESS | c.3030G>T p.L1010= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as rs1306526578; called by muse, mutect2, varscan2
- UNCX | c.429C>T p.D143= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs1251420859, COSV100310336; called by muse, mutect2, varscan2
- CDH15 | chr16:89168517 A>G | 5'Flank (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- CEP120 | c.464-3970T>A | Intron (SNP) | VAF 53/210 reads (25%) | called by muse, mutect2, varscan2
- DCHS2 | n.3155C>A | RNA (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- GAK | c.3283+145G>T | Intron (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- MIR4739 | chr17:79707490 T>A | 5'Flank (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- MUC19 | chr12:40544376 G>T | 3'Flank (SNP) | VAF 8/174 reads (5%) | catalogued as rs1290198851; called by muse, mutect2
- PCNT | c.*3A>T | 3'UTR (SNP) | VAF 84/531 reads (16%) | called by muse, mutect2, varscan2
- PIEZO1 | c.161-858T>A | Intron (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2
- SLC30A5 | c.274-669A>G | Intron (SNP) | VAF 42/288 reads (15%) | called by muse, mutect2, varscan2
- TTC39A | c.999+73del | Intron (DEL) | VAF 28/209 reads (13%) | called by mutect2, pindel, varscan2
